Somatic mutation profile of tumor specimen MMRF_2330_1_BM_CD138pos (aliquot MMRF_2330_1_BM_CD138pos_T2_KHS5U_K14050) from MMRF case MMRF_2330, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.4 years (21,343 days).
Specimen MMRF_2330_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27a59181-cc93-41c8-8ac0-52cddb6f31d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2330_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2330_1_PB_Whole_C1_KHS5U_K14051; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9539c74-b324-43b4-8d9c-f7b57a8c2362

The open-access MAF lists 124 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 33, Silent 19, Intron 16, RNA 5, 5'UTR 2, 3'Flank 2, Frame Shift Del 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAMKV | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 80/124 reads (65%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs773741414; called by muse, mutect2, varscan2
- CRTC2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV57846459; called by muse, mutect2, varscan2
- CT47B1 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs746898363; called by muse, varscan2
- DNM2 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs587778235, COSV100117276; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- EIF2AK1 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1320565463; called by muse, mutect2, varscan2
- FRMD8 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1342232949; called by muse, mutect2, varscan2
- IGHV1-69 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 92/103 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs374017972; called by muse, mutect2, varscan2
- IGHV2-70 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs765459987; called by muse, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGHV2-70 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs548028630; called by muse, varscan2
- IGHV2-70 | c.8T>A p.I3K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374765470; called by mutect2, varscan2
- IGHV3-30 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as rs572918042; called by muse, mutect2, varscan2
- IGKV4-1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs188769218; called by muse, mutect2
- IGLV3-25 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs181874336; called by muse, mutect2, varscan2
- LAMC3 | c.2446G>A p.V816M | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs576989735, COSV63090250; called by muse, mutect2, varscan2
- PCDHA3 | c.550A>T p.R184* | Nonsense Mutation (SNP) | VAF 31/150 reads (21%) | catalogued as COSV65367975; called by muse, mutect2, varscan2
- POLM | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs774514038; called by muse, mutect2, varscan2
- PRSS1 | c.265A>T p.N89Y | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.618); catalogued as rs755816580; called by muse, varscan2
- RCC1L | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1005244707; called by mutect2, varscan2
- SARDH | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs1052342276; called by muse, mutect2, varscan2
- SNX20 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs375118669; called by muse, mutect2, varscan2
- ADNP | c.2162A>G p.Q721R | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAD | c.1384C>G p.Q462E | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CCNL1 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- COL1A1 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH5 | c.1856A>G p.N619S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- DOCK5 | c.5038G>A p.V1680I | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOLK | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DSP | c.8516C>A p.S2839Y | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- FOXK1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GSDMC | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HSPA4L | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INTS13 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC9 | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NOTCH2 | c.1920del p.N641Ifs*61 | Frame Shift Del (DEL) | VAF 36/185 reads (19%) | called by mutect2, pindel, varscan2
- OTOGL | c.5272C>T p.P1758S (on ENST00000547103; = p.P1749S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RY8 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PLA2G4A | c.1597C>G p.R533G | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PROM1 | c.389T>A p.F130Y | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRB | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2
- PTPRF | c.4832G>T p.G1611V | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP2 | c.4630G>A p.E1544K | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SH2D3A | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2
- ST3GAL3 | c.728T>C p.L243P (on ENST00000361392 / NM_174964.4; = p.L228P on NM_006279.5) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDFY3 | c.2051T>C p.L684P | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AKR7A3 | c.990C>T p.F330= | Silent (SNP) | VAF 136/284 reads (48%) | catalogued as rs1355716323; called by muse, mutect2
- ARID4A | c.1797T>G p.T599= | Silent (SNP) | VAF 90/182 reads (49%) | called by muse, mutect2, varscan2
- ATP23 | c.483C>T p.C161= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- BTD | c.951G>A p.V317= | Silent (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- EFNA2 | c.180G>C p.T60= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- FRY | c.5034C>T p.Y1678= | Silent (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- FYN | c.1494C>T p.L498= | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as rs751427070; called by muse, mutect2, varscan2
- HEXB | c.841C>A p.R281= | Silent (SNP) | VAF 69/221 reads (31%) | called by muse, mutect2, varscan2
- ICE1 | c.255A>G p.L85= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs752421791; called by muse, mutect2, varscan2
- KIAA1958 | c.1890C>T p.Y630= | Silent (SNP) | VAF 65/199 reads (33%) | catalogued as COSV61725230; called by muse, mutect2, varscan2
- KLHL21 | c.1518C>T p.S506= | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- LTB | c.168G>A p.T56= | Silent (SNP) | VAF 152/317 reads (48%) | catalogued as rs749707085, COSV53000372; called by muse, mutect2, varscan2
- LZTS2 | c.1653C>T p.L551= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.1068G>A p.A356= | Silent (SNP) | VAF 26/28 reads (93%) | catalogued as rs139857191; called by muse, mutect2, varscan2
- SEZ6L | c.156G>A p.P52= | Silent (SNP) | VAF 180/364 reads (49%) | catalogued as rs778789856; called by muse, mutect2, varscan2
- SPN | c.1071G>A p.A357= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs914647648; called by muse, mutect2, varscan2
- TDRD5 | c.2445G>A p.L815= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs763127224; called by muse, mutect2, varscan2
- TECTA | c.156C>T p.A52= | Silent (SNP) | VAF 29/276 reads (11%) | called by muse, mutect2, varscan2
- ZNF77 | c.1182C>T p.Y394= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs1331370549; called by muse, mutect2, varscan2
- AC009729.1 | n.514T>A | RNA (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- AC024651.2 | n.677T>A | RNA (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- AC123912.3 | n.637C>A | RNA (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- ADO | c.*425T>G | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- AP001122.1 | n.489C>T | RNA (SNP) | VAF 29/193 reads (15%) | catalogued as rs887645632; called by muse, mutect2, varscan2
- ARHGAP5 | c.*2179A>G | 3'UTR (SNP) | VAF 51/112 reads (46%) | catalogued as rs1045599170; called by muse, mutect2, varscan2
- BCL7A | chr12:122021153 G>A | 5'Flank (SNP) | VAF 22/97 reads (23%) | catalogued as COSV55847562, COSV55847818; called by muse, mutect2, varscan2
- BTN3A1 | c.*813A>T | 3'UTR (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- CLU | c.-29-373G>T | Intron (SNP) | VAF 70/404 reads (17%) | called by muse, mutect2, varscan2
- COL1A1 | c.472-23C>G | Intron (SNP) | VAF 55/390 reads (14%) | called by muse, varscan2
- COL1A1 | c.472-109C>G | Intron (SNP) | VAF 34/234 reads (15%) | called by muse, varscan2
- COL4A4 | c.*2906C>T | 3'UTR (SNP) | VAF 17/72 reads (24%) | catalogued as rs775355828; called by muse, mutect2, varscan2
- CST4 | c.*227C>T | 3'UTR (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- CYFIP1 | chr15:22868385 T>G | 3'Flank (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- DDX54 | c.*1385T>C | 3'UTR (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- DGKI | chr7:137390369 T>C | 3'Flank (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- DNAAF3 | c.*330C>T | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- DNM3 | c.1911+1559T>A | Intron (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- DOCK5 | c.*2399C>T | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- ELK3 | c.*930del | 3'UTR (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- FBXO40 | c.*3050T>G | 3'UTR (SNP) | VAF 44/72 reads (61%) | called by muse, mutect2, varscan2
- FBXW7 | c.726+61A>C | Intron (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- FSHB | c.*127C>T | 3'UTR (SNP) | VAF 19/107 reads (18%) | catalogued as rs927511854; called by muse, mutect2, varscan2
- GNG2 | c.-30+16808C>G | Intron (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- GPATCH2 | c.1098+427G>T | Intron (SNP) | VAF 11/60 reads (18%) | catalogued as rs1274056768; called by muse, varscan2
- GPR179 | c.*510A>G | 3'UTR (SNP) | VAF 17/17 reads (100%) | catalogued as rs1468940627; called by muse, mutect2, varscan2
- GPR55 | c.-98G>A | 5'UTR (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- GULP1 | c.844-602T>A | Intron (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- HOXC8 | c.*39T>G | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- HSPA4L | c.*321T>A | 3'UTR (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.*1557G>T | 3'UTR (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
- ITGA2 | c.*2947T>A | 3'UTR (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- KANSL1 | c.1289+29C>G | Intron (SNP) | VAF 42/539 reads (8%) | called by muse, mutect2
- KRTAP19-7 | c.*150del | 3'UTR (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- LINC01553 | n.1263G>C | RNA (SNP) | VAF 19/286 reads (7%) | called by muse, mutect2
- LRR1 | c.184-804G>C | Intron (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- LRRC1 | c.*233A>C | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*3494T>A | 3'UTR (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- MECP2 | c.*5188T>A | 3'UTR (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- MSI2 | c.727+4536G>A | Intron (SNP) | VAF 20/265 reads (8%) | called by muse, mutect2
- NEGR1 | c.*2928A>G | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*259C>G | 3'UTR (SNP) | VAF 73/115 reads (63%) | called by muse, mutect2, varscan2
- NME1 | c.-5+497del | Intron (DEL) | VAF 14/81 reads (17%) | catalogued as rs201290301, COSV50148304; called by pindel, varscan2
- NR2F2 | c.*637G>T | 3'UTR (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- NUDT21 | c.*3545T>C | 3'UTR (SNP) | VAF 49/51 reads (96%) | called by muse, mutect2, varscan2
- OPRD1 | c.*262G>A | 3'UTR (SNP) | VAF 19/36 reads (53%) | catalogued as rs904614483; called by muse, mutect2, varscan2
- OTX2 | c.*879G>T | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- PC | c.1368+3305G>T | Intron (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- PDYN | c.*1134del | 3'UTR (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- PHAX | c.*2140G>A | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- PRR23C | c.-157G>A | 5'UTR (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- PTPRE | c.*2506T>C | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- RASGEF1B | c.438+592A>C | Intron (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- RPS27L | c.226+637A>C | Intron (SNP) | VAF 37/51 reads (73%) | called by muse, mutect2, varscan2
- TNIK | c.*1715dup | 3'UTR (INS) | VAF 36/116 reads (31%) | catalogued as rs1004561186; called by mutect2, varscan2
- TREML2 | c.*776C>T | 3'UTR (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- TSPAN5 | c.*1537T>G | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- USP20 | c.2513-28G>C | Intron (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- VSTM5 | c.*475C>G | 3'UTR (SNP) | VAF 74/172 reads (43%) | called by muse, mutect2, varscan2
